Surgical pathology report (de-identified scan), TCGA case TCGA-W2-A7H5, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Medical College of Wisconsin, specimen TCGA-W2-A7H5-01B (Primary Tumor).

[page 1 of 2]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

SURG PATH FINAL REPORT:

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

A. Left adrenal pheochromocytoma

Clinical Notes:

A) Fresh tissue saved for
diagnosis: Adrenal mass.

tissue bank. Pre-op

Diagnosis:

A. Left adrenal pheochromocytoma, adrenalectomy:
- Pheochromocytoma.

Note: the tumor is confined within the adrenal
gland; there is no evidence of capsular or
vascular invasion.

(Electronically signed by)

Verified:

Gross:

A. The specimen is labeled "left adrenal pheochromocytoma."
Received fresh is an 8.0 gram, 3.0 x 2.5 x 1.5 cm, ovoid tan
nodule with a small amount of adherent adipose tissue. The
outer surface is marked with black ink. The specimen is
received previously incised to reveal a red-brown soft cut
surface of the nodule with a thin rim of orange-tan cortical
tissue. A portion of the tissue is taken by
tissue bank. The remaining tissue is then submitted
entirely in cassettes A1-5.

Microscopic:

A histological examination has been performed.

ICD-O-3
Pheochromocytoma NOS
8702/0
Site Adrenal gland NOS
C74.9
JW 9/4/13

[page 2 of 2]
Administrative Notes:

Accession #:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

Source: NCI Genomic Data Commons file 30a182c2-2592-4cff-906f-9a2a202b17ed (TCGA-W2-A7H5.C9BC48EB-1CD7-4FDB-A4F1-5334840D294B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).